Somatic mutation profile of tumor specimen 0DSEL6 from CCDI case PBCHYC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 8.2 years (3,011 days).
Specimen 0DSEL6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fecbbd71-b71c-4366-91f2-aa5b299cc075.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEKX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/598091cd-68ee-41e9-8559-d57438dab528

The open-access MAF lists 49 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Intron 4, 3'UTR 2, Nonsense Mutation 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD101 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 52/1021 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs529866838, COSV56716276; called by muse, mutect2
- CDK8 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 47/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67423785; called by muse, mutect2, varscan2
- MDGA2 | c.2743C>T p.Q915* (on ENST00000399232 / NM_001113498.2; = p.Q617* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 30/760 reads (4%) | catalogued as COSV62087831; called by muse, mutect2
- MERTK | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 34/718 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745461381, COSV54928816; called by muse, mutect2
- NCOA1 | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 69/612 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1323910025, COSV99947237; called by muse, mutect2, varscan2
- PTPRS | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 183/284 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1416280955, COSV53612164; called by muse, mutect2, varscan2
- SMAP1 | c.721G>A p.D241N (on ENST00000370455 / NM_001044305.3; = p.D214N on NM_021940.5) | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.089); catalogued as rs1340943547; called by muse, mutect2
- SOX7 | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.781); catalogued as COSV58730838; called by muse, mutect2, varscan2
- TBX22 | c.1141T>G p.W381G | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV64785694; called by muse, mutect2
- TNFRSF10A | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs144670447, COSV55325211; called by muse, mutect2, varscan2
- TXK | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 130/135 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754182414, COSV51915868; called by muse, mutect2, varscan2
- UTP4 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 24/737 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs772154514; ClinVar: uncertain significance; called by muse, mutect2
- ZNF165 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs756445363; called by muse, mutect2, varscan2
- ZNF461 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 115/121 reads (95%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs764891583; called by muse, mutect2, varscan2
- ANKS3 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 107/791 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTAF1 | c.3902C>G p.S1301C | Missense Mutation (SNP) | VAF 254/563 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BTAF1 | c.3956C>G p.S1319* | Nonsense Mutation (SNP) | VAF 288/578 reads (50%) | called by muse, mutect2, varscan2
- C10orf71 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 294/560 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C9orf40 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 28/425 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.046); called by muse, mutect2
- FZD2 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.502); called by muse, mutect2
- GLG1 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 267/630 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- GPR142 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- OTOG | c.6236G>T p.C2079F | Missense Mutation (SNP) | VAF 209/220 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PROS1 | c.1299A>C p.K433N | Missense Mutation (SNP) | VAF 204/366 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RNF148 | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 227/1116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC25A12 | c.1667C>A p.T556K | Missense Mutation (SNP) | VAF 373/969 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SYNPO2L | c.1484C>A p.A495E (on ENST00000394810 / NM_001114133.3; = p.A271E on NM_024875.5) | Missense Mutation (SNP) | VAF 149/548 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF541 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 152/237 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD42 | c.1155C>T p.Y385= | Silent (SNP) | VAF 94/809 reads (12%) | catalogued as rs370536747; called by muse, mutect2, varscan2
- DOCK9 | c.4827G>T p.T1609= (on ENST00000376460 / NM_001366676.2; = p.T1610= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/697 reads (9%) | catalogued as rs759695289; called by muse, mutect2
- EIF3A | c.2859C>T p.D953= | Silent (SNP) | VAF 228/395 reads (58%) | catalogued as rs148664870; called by muse, mutect2, varscan2
- FAT3 | c.2955A>C p.I985= | Silent (SNP) | VAF 219/673 reads (33%) | called by muse, mutect2, varscan2
- FBLN7 | c.1305C>A p.S435= | Silent (SNP) | VAF 258/688 reads (38%) | catalogued as rs1558899768; called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.495C>T p.H165= | Silent (SNP) | VAF 610/1072 reads (57%) | called by muse, mutect2, varscan2
- MYH9 | c.3816C>T p.A1272= | Silent (SNP) | VAF 45/332 reads (14%) | catalogued as rs752273735; called by muse, mutect2, varscan2
- OR2G3 | c.537C>T p.C179= | Silent (SNP) | VAF 442/958 reads (46%) | catalogued as rs144392521, COSV60683676; called by muse, mutect2, varscan2
- P2RY2 | c.288C>T p.G96= | Silent (SNP) | VAF 164/591 reads (28%) | called by muse, mutect2, varscan2
- PDILT | c.621G>T p.T207= | Silent (SNP) | VAF 194/703 reads (28%) | called by muse, mutect2, varscan2
- PRPS1L1 | c.507G>A p.S169= | Silent (SNP) | VAF 197/671 reads (29%) | catalogued as rs948237895, COSV101552908; called by muse, mutect2, varscan2
- RPS6KA2 | c.1689G>A p.A563= | Silent (SNP) | VAF 292/323 reads (90%) | catalogued as rs774396701, COSV55819232, COSV99691929; called by muse, mutect2, varscan2
- SFXN4 | c.786G>A p.L262= | Silent (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- BTF3 | c.316-54G>T | Intron (SNP) | VAF 45/58 reads (78%) | catalogued as rs372028278; called by muse, mutect2, varscan2
- LILRB1 | c.1801-21C>A | Intron (SNP) | VAF 230/303 reads (76%) | called by muse, mutect2, varscan2
- LRCH1 | c.1527+89G>C | Intron (SNP) | VAF 17/108 reads (16%) | catalogued as COSV60848163; called by muse, mutect2, varscan2
- MST1L | n.1409A>T | RNA (SNP) | VAF 72/784 reads (9%) | called by muse, mutect2, varscan2
- PPM1F | c.355+59C>T | Intron (SNP) | VAF 127/144 reads (88%) | catalogued as rs551190395, COSV99601693; called by muse, mutect2, varscan2
- RAB14 | c.*62T>C | 3'UTR (SNP) | VAF 92/99 reads (93%) | called by muse, mutect2, varscan2
- TIGD2 | c.-8C>T | 5'UTR (SNP) | VAF 51/265 reads (19%) | called by muse, mutect2, varscan2
- TOMM40L | c.*12G>A | 3'UTR (SNP) | VAF 44/903 reads (5%) | called by muse, mutect2
